Gene-level copy-number profile of tumor specimen TCGA-CV-7090-01A from TCGA case TCGA-CV-7090, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 39.7 years (14,515 days).
Specimen TCGA-CV-7090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.710969b9-0423-43c3-9274-f733e99acbf3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7090-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0715d20e-05da-4064-80ea-ab64fcfc3d0b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 764; copy number 2: 14,622; copy number 3: 21,941; copy number 4: 9,725; copy number 5: 7,341; copy number 6: 3,633; copy number 7: 1; copy number 8: 302; copy number 9: 1,324; copy number 10: 38; copy number 11: 56; copy number 16: 15; copy number 22: 36; copy number 54: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7090-01A-11D-2010-01): tumor purity 0.38, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,785 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,725,674–94,947,341, 15 genes, copy number 16: CNN2P11, GXYLT1P7, CNN2P8, AC073464.2, CYP4F32P, AC073464.1, SNX18P14, ANKRD20A8P, RNU6-1320P, SOWAHCP5, AC097374.1, TEKT4, MTCO1P48, MTCO3P45, RPS24P6.
- chr4:24,517,441–26,490,484, 37 genes, copy number 7–22 (within-gene range 7–36): DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR.
- chr4:35,948,221–37,700,002, 18 genes, copy number 9–11: ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1, AC093746.1, LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA.
- chr7:38,256,337–38,311,808, 9 genes, copy number 11: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr8:37,908,738–39,730,065, 51 genes, copy number 8: RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr8:43,672,823–145,066,685, 1,536 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr9:13,105,706–14,398,983, 13 genes, copy number 54 (within-gene range 3–54): MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1.
- chr14:21,924,063–22,506,702, 77 genes, copy number 10–11 (broad region; genes not listed).
- chr18:20,946,906–22,051,159, 29 genes, copy number 8 (within-gene range 4–8): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900.

Autosomal genes at a single copy (total copy number 1): 754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
